CCDI case PBBNNR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/016f3f5d-b93b-41d5-aedd-6580a798515c

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,278 days).

Biospecimens (3 samples)
- Sample 0DDEQ8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDEQ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DDEQH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
